Somatic mutation profile of tumor specimen eb3f3494-7057-4afe-b212-e6e9a3 (aliquot eb3f3494-7057-4afe-b212-e6e9a3_D6_2) from CPTAC case 04OV017, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen eb3f3494-7057-4afe-b212-e6e9a3: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8989436d-a24b-4722-bd32-7112db3bdd99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 7401f279-d5a9-4555-890d-19c38f (Blood Derived Normal), aliquot 7401f279-d5a9-4555-890d-19c38f_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4feadd3-9aec-406f-88bc-34ecd3f39470

The open-access MAF lists 108 somatic variants for this specimen: 73 protein-altering or splice-affecting, 20 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 20, Nonsense Mutation 7, Intron 5, RNA 5, 5'UTR 4, Frame Shift Del 2, Frame Shift Ins 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABI3 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as rs556355860; called by muse, mutect2, varscan2
- AKT1 | c.1339A>T p.I447F | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV62572672, COSV62576349; called by muse, mutect2, varscan2
- ATM | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53777746; called by muse, mutect2, varscan2
- CEACAM7 | c.767T>C p.I256T | Missense Mutation (SNP) | VAF 78/106 reads (74%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs371586723; called by muse, mutect2, varscan2
- CRYBG2 | c.333G>C p.E111D | Missense Mutation (SNP) | VAF 47/266 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1363896392; called by muse, mutect2, varscan2
- DISC1 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 50/590 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs150138912; called by muse, mutect2
- ERCC2 | c.711C>G p.H237Q | Missense Mutation (SNP) | VAF 178/1116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55545049; called by mutect2, varscan2
- EXTL3 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 157/957 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs554162593, COSV55039858; called by muse, mutect2, varscan2
- FADS2 | c.687G>C p.K229N | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53900603; called by mutect2, varscan2
- ITPR1 | c.5458G>C p.V1820L (on ENST00000354582; = p.V1765L on NM_002222.7) | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as rs745457761; called by muse, mutect2
- KRT78 | c.80G>T p.R27M | Missense Mutation (SNP) | VAF 83/148 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.275); catalogued as rs768898661; called by muse, mutect2, varscan2
- MSANTD2 | c.1069C>T p.R357W (on ENST00000374979 / NM_001308027.2; = p.R305W on NM_024631.4) | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs371397423; called by muse, mutect2
- OR10R2 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV63768465; called by muse, mutect2, varscan2
- OR7A5 | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 45/319 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); catalogued as rs778267632; called by muse, mutect2, varscan2
- PCDHA1 | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 69/304 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.02); catalogued as rs1374636637, COSV65374759; called by muse, mutect2, varscan2
- PTPRC | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs866816038, COSV61412614; called by muse, mutect2
- RAD51AP2 | c.2086G>A p.D696N | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.322); catalogued as COSV67587721; called by muse, mutect2, varscan2
- RGPD3 | c.369A>T p.K123N | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV100449590; called by muse, mutect2, varscan2
- SPATA24 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs975907566; called by muse, mutect2, varscan2
- SPTBN5 | c.3147G>C p.E1049D | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs761073670; called by muse, mutect2, varscan2
- TBX5 | c.791G>T p.R264M | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as CM161968; called by muse, mutect2, varscan2
- TDRD15 | c.3533G>A p.R1178H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs776764574; called by muse, mutect2, varscan2
- TNXB | c.4705G>A p.D1569N (on ENST00000647633; = p.D1322N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs1280340355, COSV100925874; called by muse, mutect2, varscan2
- TOP3A | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.608); catalogued as rs182958315; called by muse, mutect2, varscan2
- USP21 | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 63/228 reads (28%) | catalogued as rs759996638; called by muse, mutect2, varscan2
- ZAP70 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 144/671 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); catalogued as rs1369094426, COSV53853074; called by muse, mutect2, varscan2
- ZNF208 | c.2581T>G p.Y861D | Missense Mutation (SNP) | VAF 37/306 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68113883; called by muse, mutect2, varscan2
- ADAMTS16 | c.3343C>A p.P1115T | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.276); called by mutect2, varscan2
- BCORL1 | c.3299C>A p.A1100D | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CACNA2D1 | c.1672A>G p.T558A (on ENST00000356253 / NM_001366867.1; = p.T539A on NM_000722.4) | Missense Mutation (SNP) | VAF 67/270 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- CBX4 | c.1425G>T p.L475F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, varscan2
- CCDC30 | c.1639A>T p.K547* (on ENST00000340612; = p.K504* on NM_001080850.3) | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2
- CLCF1 | c.236T>G p.L79R | Missense Mutation (SNP) | VAF 83/96 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CWC25 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DCLK2 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCP1B | c.88C>G p.R30G | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- DENND2B | c.1834C>G p.R612G | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- DNAH11 | c.9977A>G p.E3326G | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- ERCC8 | c.725C>A p.T242N | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- FAM86B1 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 90/1240 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); called by muse, mutect2
- FGF10 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 80/486 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GAB2 | c.1111C>T p.Q371* (on ENST00000361507 / NM_080491.3; = p.Q333* on NM_012296.3) | Nonsense Mutation (SNP) | VAF 76/540 reads (14%) | called by muse, mutect2, varscan2
- GPRC6A | c.53C>A p.S18* | Nonsense Mutation (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- GRM6 | c.1386G>C p.E462D | Missense Mutation (SNP) | VAF 91/509 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GSX1 | c.743_777del p.M248Tfs*31 | Frame Shift Del (DEL) | VAF 72/213 reads (34%) | called by mutect2, pindel
- HESX1 | c.411dup p.R138* | Frame Shift Ins (INS) | VAF 24/161 reads (15%) | called by mutect2, pindel, varscan2
- KCNMB1 | c.307-1_313delinsA p.X103_splice | Splice Site (DEL) | VAF 18/162 reads (11%) | called by pindel, varscan2*
- KMO | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAGEB6 | c.1062C>A p.C354* | Nonsense Mutation (SNP) | VAF 84/235 reads (36%) | called by muse, mutect2, varscan2
- OR10Z1 | chr1:158607379 del GAA | Missense Mutation (DEL) | VAF 11/117 reads (9%) | called by mutect2, pindel
- OR52E8 | c.521T>C p.F174S | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PLXNA3 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PRAMEF17 | c.1330G>T p.V444F | Missense Mutation (SNP) | VAF 85/550 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRKDC | c.2854G>T p.G952* | Nonsense Mutation (SNP) | VAF 69/122 reads (57%) | called by muse, mutect2, varscan2
- PRKRA | c.721T>G p.Y241D | Missense Mutation (SNP) | VAF 68/350 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PSEN2 | c.850A>T p.R284* | Nonsense Mutation (SNP) | VAF 179/694 reads (26%) | called by muse, mutect2, varscan2
- ROBO1 | c.4901G>A p.G1634E | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ROMO1 | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 43/288 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SIGLECL1 | c.131T>A p.V44D | Missense Mutation (SNP) | VAF 60/479 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC28A2 | c.1753C>G p.L585V | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- SLC38A8 | c.1154T>A p.I385N | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC66A1 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SON | c.6956G>C p.R2319T | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- SPAG6 | c.899A>T p.D300V | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- SULT6B1 | c.613G>C p.D205H (on ENST00000535679 / NM_001367551.1; = p.D167H on NM_001032377.2) | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TDRD15 | c.1355G>A p.G452E | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- TEDDM1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 46/289 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- TP53BP2 | c.3396C>G p.S1132R (on ENST00000343537 / NM_001031685.3; = p.S1003R on NM_005426.2) | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- UBTFL1 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 27/272 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- ZNF274 | c.397G>C p.A133P (on ENST00000610905; = p.A28P on NM_016324.3) | Missense Mutation (SNP) | VAF 49/443 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ZNF329 | c.377del p.G126Efs*17 | Frame Shift Del (DEL) | VAF 41/382 reads (11%) | called by mutect2, pindel, varscan2
- ZNF518A | c.1747C>T p.L583F | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF658 | c.2651G>A p.C884Y | Missense Mutation (SNP) | VAF 112/546 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- CEACAM21 | c.558C>T p.V186= | Silent (SNP) | VAF 50/493 reads (10%) | called by muse, mutect2, varscan2
- CUX2 | c.2208G>A p.A736= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as rs1210746936, COSV55626463; called by muse, mutect2, varscan2
- DCLRE1B | c.489C>T p.H163= | Silent (SNP) | VAF 33/150 reads (22%) | called by muse, mutect2, varscan2
- DHX15 | c.189T>C p.A63= | Silent (SNP) | VAF 73/422 reads (17%) | catalogued as COSV100391140; called by muse, mutect2, varscan2
- DIRAS1 | c.411G>A p.A137= | Silent (SNP) | VAF 88/229 reads (38%) | catalogued as rs1391183554; called by muse, varscan2
- EID2 | c.633G>C p.T211= | Silent (SNP) | VAF 60/375 reads (16%) | called by muse, mutect2, varscan2
- EPRS1 | c.1914C>T p.D638= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs372683669, COSV65098825; called by muse, mutect2, varscan2
- GCN1 | c.6744C>T p.G2248= | Silent (SNP) | VAF 38/165 reads (23%) | catalogued as rs1288667088, COSV56103803; called by muse, mutect2, varscan2
- GGT1 | c.765C>T p.N255= | Silent (SNP) | VAF 85/469 reads (18%) | catalogued as rs756899508; called by muse, mutect2, varscan2
- GRM6 | c.537G>A p.P179= | Silent (SNP) | VAF 360/500 reads (72%) | catalogued as rs771271291, COSV51437628; called by muse, varscan2
- NAGS | c.195C>T p.G65= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as rs1413099790; called by muse, mutect2, varscan2
- OR1A1 | c.225G>A p.S75= | Silent (SNP) | VAF 94/406 reads (23%) | catalogued as rs113780617, COSV58404194; called by muse, mutect2, varscan2
- OR51V1 | c.741C>T p.H247= | Silent (SNP) | VAF 51/191 reads (27%) | called by muse, mutect2, varscan2
- PRAMEF19 | c.1275C>T p.V425= | Silent (SNP) | VAF 61/868 reads (7%) | called by muse, mutect2
- PTGIS | c.18C>A p.L6= | Silent (SNP) | VAF 8/29 reads (28%) | called by muse, varscan2
- RAN | c.78C>T p.F26= | Silent (SNP) | VAF 19/218 reads (9%) | catalogued as rs116832702; called by muse, mutect2
- SLC46A3 | c.1071G>C p.P357= | Silent (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- SLC52A3 | c.1395G>A p.L465= | Silent (SNP) | VAF 47/447 reads (11%) | called by muse, mutect2, varscan2
- SUSD3 | c.672G>A p.Q224= | Silent (SNP) | VAF 47/229 reads (21%) | catalogued as COSV64937546; called by muse, mutect2, varscan2
- UVSSA | c.321G>A p.Q107= | Silent (SNP) | VAF 120/187 reads (64%) | catalogued as rs1198959272; called by muse, mutect2, varscan2
- AC244258.1 | n.583G>C | RNA (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2
- ATIC | c.19+39C>T | Intron (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- BCAS3 | c.2639-3309C>T | Intron (SNP) | VAF 9/58 reads (16%) | catalogued as rs1262581161; called by muse, mutect2, varscan2
- FAM25C | c.-21G>A | 5'UTR (SNP) | VAF 106/317 reads (33%) | catalogued as rs1298736034; called by muse, mutect2, varscan2
- GRAMD2B | c.-12G>C | 5'UTR (SNP) | VAF 32/122 reads (26%) | catalogued as rs754446207; called by muse, mutect2, varscan2
- GRK4 | c.*8G>A | 3'UTR (SNP) | VAF 30/98 reads (31%) | called by muse, mutect2, varscan2
- IK | c.16+30C>T | Intron (SNP) | VAF 53/272 reads (19%) | called by muse, mutect2, varscan2
- LINC01276 | n.610G>C | RNA (SNP) | VAF 28/155 reads (18%) | called by muse, mutect2, varscan2
- NDUFS6 | c.-7G>A | 5'UTR (SNP) | VAF 191/388 reads (49%) | called by muse, mutect2, varscan2
- PPAN | c.292-96A>G | Intron (SNP) | VAF 53/427 reads (12%) | called by muse, mutect2, varscan2
- SMIM8 | n.607C>A | RNA (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.3120G>C | RNA (SNP) | VAF 85/371 reads (23%) | called by muse, mutect2, varscan2
- SUGT1P4-STRA6LP | n.1162G>A | RNA (SNP) | VAF 89/181 reads (49%) | catalogued as rs551206410; called by muse, mutect2, varscan2
- ZNF749 | c.-1G>A | 5'UTR (SNP) | VAF 54/389 reads (14%) | called by muse, mutect2, varscan2
- ZNF821 | c.-78+39C>T | Intron (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
